Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0LS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0LS-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

adenocarcinoma, endometrioid, nos 8380/3

Site: endometrium C54.1

lu 5/1/11

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes and ovaries
- 2: SP: Right para-aortic lymph nodes (
- 3: SP: Left external iliac lymph nodes (
- 4: SP: Left obturator lymph nodes (
- 5: SP: Right external iliac lymph nodes (
- 6: SP: Right obturator lymph nodes (

DIAGNOSIS:

- 1) UTERUS, CERVIX, FALLOPIAN TUBES AND OVARIES; TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, FIGO GRADE 2.
- THE TUMOR INVADES TO $\leq$ HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS APPROXIMATELY 6 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 28 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- VASCULAR INVASION IS PRESENT.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY(IES): ADENOMYOSIS AND LEIOMYOMA(S).
- THERE IS A RIGHT PERITUBAL CELLULAR FIBROMA.
- ALL OTHER ADNEXAL STRUCTURES ARE UNREMARKABLE.
- 2) LYMPH NODE, RIGHT PARA-AORTIC; BIOPSY:
- FIBROADIPOSE TISSUE WITH A MINUTE, BENIGN LYMPHOID AGGREGATE.
- 3) LYMPH NODE, EXTERNAL ILIAC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 4) LYMPH NODES, LEFT OBTURATOR; BIOPSY:
- SIX BENIGN LYMPH NODES (0/6).
- 5) LYMPH NODE, EXTERNAL ILIAC; BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).

** Continued on next page **

[page 2 of 2]
- HISTIOCYTOSIS

Page 2 of 5

- 6) LYMPH NODES, RIGHT OBTURATOR; BIOPSY:
- FIVE BENIGN LYMPH NODES (0/5).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 8a31da5a-cd75-45fe-a585-559aa6568d51 (TCGA-AP-A0LS.E802CEF6-BC3F-4C35-85E8-2B37531571CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).